Gene-level copy-number profile of tumor specimen TCGA-ZB-A96L-01A from TCGA case TCGA-ZB-A96L, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 70.9 years (25,914 days).
Specimen TCGA-ZB-A96L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.eceb2ca2-1f57-4af1-85c4-9bc0c52f0d6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZB-A96L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c6eef89-508a-43e9-b26d-f689d48dfaef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 5; copy number 2: 3,873; copy number 3: 139; copy number 4: 51,339; copy number 5: 12; copy number 6: 3,937; copy number 7: 171; copy number 8: 75; copy number 10: 123; copy number 11: 22; copy number 12: 13; copy number 13: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZB-A96L-01A-11D-A427-01): tumor purity 0.81, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–23,438,700, 23 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 241 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,873,347–50,504,244, 38 genes, copy number 10: ACTBP13, MST1R, AC105935.2, AC105935.1, MON1A, RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131.
- chr3:90,030,284–91,513,775, 6 genes, copy number 11: U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr17:28,018,770–28,903,079, 83 genes, copy number 13 (broad region; genes not listed).
- chr17:60,677,453–61,392,838, 1 gene, copy number 12 (within-gene range 6–12): BCAS3.
- chr17:61,034,636–61,485,110, 12 genes, copy number 12 (within-gene range 6–12): AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.
- chr17:68,206,076–69,060,949, 16 genes, copy number 11 (within-gene range 6–11): AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9.
- chr19:94,062–1,322,846, 85 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
